Somatic mutation profile of tumor specimen TCGA-49-AAR0-01A (aliquot TCGA-49-AAR0-01A-21D-A397-08) from TCGA case TCGA-49-AAR0, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.3 years (20,932 days).
Specimen TCGA-49-AAR0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b44c03fa-b8b0-40ad-9092-f3818640f4cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AAR0-11A (Solid Tissue Normal), aliquot TCGA-49-AAR0-11A-11D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/272f8df5-b85b-4fa9-b3ad-336c028d761a

The open-access MAF lists 139 somatic variants for this specimen: 103 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 32, Nonsense Mutation 9, Frame Shift Del 3, Intron 2, Splice Site 2, 3'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); catalogued as rs1359582062, CD051785, CM044076, COSV58820485, COSV58828619, COSV58831044; called by muse, mutect2, varscan2
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY10 | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100897068; called by muse, mutect2, varscan2
- ANK2 | c.5326C>T p.R1776* | Nonsense Mutation (SNP) | VAF 15/154 reads (10%) | catalogued as COSV52168969; called by muse, mutect2
- BCAN | c.2462T>A p.L821Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100228460; called by muse, mutect2, varscan2
- BMPR2 | c.2662G>T p.V888L | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV101001635; called by muse, mutect2, varscan2
- BRD8 | c.2876C>T p.P959L | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs553603929, COSV99649044; called by muse, mutect2, varscan2
- CCSER1 | c.923C>A p.T308K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.009); catalogued as COSV100395818; called by muse, mutect2, varscan2
- CFAP52 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100235544; called by muse, mutect2, varscan2
- CHRDL1 | c.988G>A p.D330N (on ENST00000372045; = p.D336N on NM_145234.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.434); catalogued as COSV99488657; called by muse, mutect2, varscan2
- CNBD1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | catalogued as rs531680350, COSV101575301; called by muse, mutect2
- COL11A1 | c.5171C>A p.S1724* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100617949; called by muse, mutect2, varscan2
- COL3A1 | c.4391G>T p.C1464F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111317900, COSV100483672; called by muse, mutect2, varscan2
- CTH | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1198378244, COSV100697149; called by muse, mutect2, varscan2
- DCLK1 | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV55170754, COSV99712874; called by muse, mutect2, varscan2
- DDI1 | c.457A>T p.N153Y | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100160729, COSV56374656; called by muse, mutect2
- DDX28 | c.978A>C p.L326F | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV100193134; called by muse, mutect2, varscan2
- DHX40 | c.1798C>G p.L600V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.437); catalogued as COSV99233225; called by mutect2, varscan2
- DPP6 | c.1099G>A p.D367N (on ENST00000377770 / NM_001364500.2; = p.D305N on NM_001936.5) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV100127949; called by muse, mutect2
- ERICH3 | c.3856A>G p.R1286G | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs372893157, COSV58614809; called by muse, mutect2
- ESPNL | c.2991A>T p.E997D | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100547927; called by muse, mutect2, varscan2
- EYA1 | c.1312T>C p.Y438H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100380226; called by muse, mutect2
- FAM135A | c.3980C>T p.S1327L (on ENST00000370479 / NM_001351599.1; = p.S1114L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs975809246, COSV52060053; called by muse, mutect2, varscan2
- FLG | c.11096G>A p.R3699Q | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.097); catalogued as rs754536597, COSV100911786; called by muse, mutect2
- GAA | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100163493; called by muse, mutect2
- GBP5 | c.1652A>T p.Q551L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV100600165; called by muse, mutect2, varscan2
- GJB5 | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1289240030, COSV100258677; called by muse, mutect2, varscan2
- GRIK2 | c.2188A>T p.T730S | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100029152, COSV59755718; called by muse, mutect2
- GRIN3A | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1332461912, COSV62457427; called by muse, mutect2
- HEATR5A | c.1538C>G p.A513G | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101120488; called by muse, mutect2
- HLA-DQB1 | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100891340; called by muse, mutect2
- KEAP1 | c.1531G>T p.G511C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262720, COSV50648370; called by muse, mutect2, varscan2
- KLHL15 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100044422; called by muse, mutect2, varscan2
- KNSTRN | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); catalogued as rs761730079, COSV99991973, COSV99992040; called by muse, mutect2
- LCE3A | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100175165; called by muse, mutect2, varscan2
- LRRC36 | c.1114G>C p.A372P | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV99339077; called by muse, mutect2, varscan2
- LRRC6 | c.1265A>C p.K422T | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV99138546; called by muse, mutect2
- MAP3K13 | c.728A>C p.E243A | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99407893; called by muse, mutect2, varscan2
- MFSD2B | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100601226; called by muse, mutect2, varscan2
- MMD2 | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV68661046; called by muse, mutect2
- MMD2 | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as rs1291100509, COSV101287132; called by muse, mutect2
- MRPS14 | c.98G>C p.R33T | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV100871569; called by muse, mutect2, varscan2
- MYL6 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 29/199 reads (15%) | catalogued as COSV99255271; called by muse, mutect2, varscan2
- MYOM2 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs143200815, COSV100038310; called by muse, mutect2, varscan2
- NARS2 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99807514; called by muse, mutect2
- NCAM2 | c.1522T>A p.S508T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99523375; called by muse, mutect2, varscan2
- NOTCH4 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs377458854; called by muse, mutect2
- NRP2 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 50/559 reads (9%) | catalogued as COSV55928542, COSV99785549; called by muse, mutect2
- OR10T2 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs761365250, COSV57780410; called by muse, mutect2, varscan2
- OR4L1 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59849112, COSV59849594; called by muse, mutect2
- OR56A4 | c.1024C>A p.L342M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV100417682; called by muse, mutect2, varscan2
- OR5B17 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs142401128; called by muse, mutect2, varscan2
- OR5D18 | c.604T>G p.F202V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1007197883, COSV100450884; called by muse, mutect2, varscan2
- OR8U1 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1297063221, COSV100164111; called by muse, varscan2
- PAX8 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99640063; called by muse, mutect2
- PCDHB12 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs782258906, COSV99507793; called by muse, mutect2
- PCM1 | c.5764A>T p.K1922* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100279552; called by muse, mutect2
- PHLDB1 | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.108); catalogued as COSV100616760; called by muse, mutect2, varscan2
- PPP2R1A | c.995A>T p.E332V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100436460; called by muse, mutect2, varscan2
- PRKACB | c.978C>G p.S326R | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100854107; called by muse, mutect2, varscan2
- PTPN21 | c.1148T>C p.I383T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs1446950664, COSV100162502; called by muse, mutect2, varscan2
- RAD51AP1 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99961493; called by muse, mutect2, varscan2
- RAD51B | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101185389; called by muse, mutect2, varscan2
- RAP1GAP | c.1252A>T p.M418L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99265846; called by muse, mutect2, varscan2
- RAP1GAP | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.221); catalogued as COSV99265853; called by muse, mutect2, varscan2
- REG1A | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1433985684, COSV99286967; called by muse, mutect2, varscan2
- RIBC2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV61581463; called by muse, mutect2
- RNF169 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1309338384, COSV100213366; called by muse, mutect2
- RPH3A | c.1955-1G>T p.X652_splice (on ENST00000389385 / NM_001143854.2; = p.X648_splice on NM_014954.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 13/113 reads (12%) | catalogued as COSV101231887; called by muse, mutect2, varscan2
- RPN1 | c.629G>A p.S210N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99957256; called by muse, mutect2
- RUFY4 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.049); catalogued as rs896040130, COSV100723214; called by muse, varscan2
- SLC35E3 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV99972043; called by muse, mutect2
- SLC8A3 | c.2087A>C p.H696P (on ENST00000381269 / NM_183002.3; = p.H694P on NM_033262.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs1421190311, COSV99385831; called by muse, mutect2, varscan2
- SNX19 | c.2706G>C p.Q902H | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99773573; called by muse, mutect2, varscan2
- SPAST | c.1824C>G p.N608K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100188721; called by muse, mutect2, varscan2
- SPATC1 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.23); catalogued as COSV101085285; called by muse, mutect2, varscan2
- SPHKAP | c.1399A>T p.I467F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100764523; called by muse, mutect2, varscan2
- SSTR4 | c.806T>G p.V269G | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99658789; called by muse, mutect2
- SVEP1 | c.6497C>T p.A2166V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99929717; called by muse, mutect2
- SYNM | c.4213C>T p.R1405* | Nonsense Mutation (SNP) | VAF 7/142 reads (5%) | catalogued as rs782243596; called by muse, mutect2
- TAB2 | c.1993G>C p.G665R | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99645086; called by muse, mutect2, varscan2
- TBC1D22A | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV100453662, COSV61437609; called by muse, mutect2, varscan2
- TCOF1 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs182776703, CD125090; called by muse, mutect2, varscan2
- TESK2 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV100517697; called by muse, mutect2, varscan2
- TEX37 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV100304680; called by muse, mutect2
- THBS2 | c.1935G>T p.V645= | Splice Region (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100828064; called by muse, mutect2
- TMCC3 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV54151943, COSV99705665; called by muse, mutect2
- TMEM38B | c.542+2T>C p.X181_splice | Splice Site (SNP) | VAF 16/63 reads (25%) | catalogued as COSV101016593; called by muse, mutect2, varscan2
- TRBV6-1 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs762964994; called by muse, mutect2, varscan2
- TREML2 | c.588C>A p.S196R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.367); catalogued as COSV101530189; called by muse, mutect2, varscan2
- TRPC3 | c.664G>T p.A222S (on ENST00000379645 / NM_001366479.2; = p.A149S on NM_003305.2) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.099); catalogued as rs749905737, COSV53380906; called by muse, mutect2, varscan2
- TUFT1 | c.1057A>T p.S353C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100777141; called by muse, varscan2
- UGT3A1 | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs1189277631, COSV57097713; called by muse, mutect2, varscan2
- UROC1 | c.1901G>T p.R634L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99332309; called by mutect2, varscan2
- VPS72 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as COSV100614551, COSV63166848; called by muse, mutect2, varscan2
- ZBTB40 | c.3451G>C p.D1151H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV100989099; called by muse, mutect2, varscan2
- ZBTB7A | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59328764; called by muse, mutect2
- ZG16B | c.264T>A p.S88R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV101206770; called by muse, mutect2, varscan2
- ZNF436 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1350301166, COSV58358998; called by muse, mutect2, varscan2
- ZWINT | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100571557; called by muse, mutect2
- CETP | c.1064del p.V355Afs*7 | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | called by mutect2, pindel, varscan2
- NEFH | c.1700del p.P567Qfs*42 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, varscan2
- TRAM1 | c.404_405delinsT p.W135Lfs*26 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by pindel, varscan2*
- ADCY2 | c.1473G>T p.S491= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs771452586, COSV57894090; called by muse, mutect2, varscan2
- ADGRL4 | c.267C>G p.G89= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100876519; called by muse, mutect2, varscan2
- CCDC170 | c.2097G>A p.V699= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV99498806; called by muse, mutect2, varscan2
- CHRD | c.2385G>A p.A795= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs760367557, COSV99200243, COSV99200256; called by muse, mutect2, varscan2
- COL26A1 | c.1325G>A p.*442= (on ENST00000313669 / NM_001278563.3; = p.*440= on NM_133457.4) | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV100562020; called by muse, mutect2, varscan2
- DYRK2 | c.687G>A p.G229= (on ENST00000344096 / NM_006482.3; = p.G156= on NM_003583.4) | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100165392; called by muse, mutect2, varscan2
- FPR2 | c.852T>A p.V284= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100389437; called by muse, mutect2, varscan2
- GABRA5 | c.201G>T p.G67= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100165738; called by muse, mutect2
- GABRR1 | c.450C>T p.V150= | Silent (SNP) | VAF 19/347 reads (5%) | catalogued as COSV101034075, COSV65619547; called by muse, mutect2
- HHIPL2 | c.939G>T p.R313= | Silent (SNP) | VAF 30/416 reads (7%) | catalogued as COSV100596708, COSV100597069; called by muse, mutect2
- HPS5 | c.1815A>T p.P605= (on ENST00000349215 / NM_181507.2; = p.P491= on NM_007216.4) | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV100752362; called by muse, mutect2, varscan2
- IGKV1D-8 | c.27C>A p.L9= | Silent (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- INPP5J | c.2415A>T p.T805= (on ENST00000331075 / NM_001284285.2; = p.T437= on NM_001002837.2) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99312037; called by muse, mutect2, varscan2
- KCNK13 | c.922C>A p.R308= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs990117046, COSV56410493, COSV99965911; called by muse, mutect2, varscan2
- L1CAM | c.2253C>T p.R751= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs782035973, COSV100649451; called by muse, mutect2
- MTOR | c.3876G>C p.L1292= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100816632; called by muse, mutect2
- MYO9A | c.4698A>T p.S1566= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100614244, COSV61856880; called by muse, mutect2, varscan2
- MYPN | c.3552C>T p.P1184= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs749396604, COSV100590569; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAALADL2 | c.2118G>T p.R706= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV101495481; called by muse, mutect2
- ODAM | c.123T>G p.L41= | Silent (SNP) | VAF 10/197 reads (5%) | catalogued as COSV101258104; called by muse, mutect2
- OR1D2 | c.594G>T p.V198= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100513971; called by muse, mutect2, varscan2
- PCDHB10 | c.2370C>T p.T790= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV53385020, COSV99504980; called by muse, mutect2, varscan2
- PCDHB6 | c.717C>A p.P239= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV50716140; called by muse, mutect2, varscan2
- RNF31 | c.831A>T p.P277= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs769494340, COSV99396276; called by muse, mutect2, varscan2
- SERPINA11 | c.381C>A p.A127= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV58243169; called by muse, mutect2, varscan2
- SERPINB4 | c.465G>A p.T155= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs374647211; called by muse, mutect2, varscan2
- SLC2A14 | c.726A>G p.K242= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as COSV100534002; called by muse, mutect2
- SYT16 | c.1542G>A p.S514= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as rs1027880448, COSV70860207; called by muse, mutect2
- TNKS1BP1 | c.3948C>A p.G1316= | Silent (SNP) | VAF 8/196 reads (4%) | catalogued as COSV100836257; called by muse, mutect2
- TRIM4 | c.501C>T p.L167= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs755841618, COSV100584410; called by muse, mutect2, varscan2
- XYLT1 | c.1578T>A p.L526= | Silent (SNP) | VAF 41/285 reads (14%) | catalogued as COSV99763221; called by muse, mutect2, varscan2
- ZYX | c.1215C>T p.F405= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs758330921, COSV99314638; called by muse, mutect2, varscan2
- FARP1 | c.171+31159C>G | Intron (SNP) | VAF 26/80 reads (33%) | catalogued as COSV100132004; called by muse, mutect2, varscan2
- SERPINA13P | n.183C>G | RNA (SNP) | VAF 6/21 reads (29%) | catalogued as rs1417507284; called by muse, mutect2, varscan2
- TRIP12 | c.99-851A>G | Intron (SNP) | VAF 23/160 reads (14%) | catalogued as COSV99390893; called by muse, mutect2, varscan2
- XIRP2 | c.*1342G>C | 3'UTR (SNP) | VAF 6/63 reads (10%) | catalogued as COSV99746945, COSV99747093; called by muse, mutect2
